Somatic mutation profile of tumor specimen TCGA-AA-A01Z-01A (aliquot TCGA-AA-A01Z-01A-11W-A096-10) from TCGA case TCGA-AA-A01Z, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 68.4 years (24,990 days).
Specimen TCGA-AA-A01Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 525a1a9b-691f-42aa-a60e-9b05fc6fa2bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01Z-11A (Solid Tissue Normal), aliquot TCGA-AA-A01Z-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/586fc7e0-0068-4409-84a1-bc9f3de6af3f

The open-access MAF lists 105 somatic variants for this specimen: 85 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 18, Frame Shift Ins 6, Nonsense Mutation 4, In Frame Del 2, Intron 1, Frame Shift Del 1, Splice Site 1, Splice Region 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 46/112 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 83/243 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- FBXW7 | c.1558G>A p.D520N (on ENST00000281708 / NM_001349798.2; = p.D440N on NM_018315.5) | Missense Mutation (SNP) | VAF 66/215 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895090, COSV55923112, COSV55961967; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/114 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NALCN | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 52/103 reads (50%) | catalogued as rs376152742; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101037728; called by muse, mutect2, varscan2
- ADAMTS20 | c.5536C>T p.Q1846* | Nonsense Mutation (SNP) | VAF 69/210 reads (33%) | catalogued as COSV67135744; called by muse, mutect2, varscan2
- ADAMTSL3 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 137/399 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs757231468, COSV99720791; called by muse, mutect2, varscan2
- ADNP | c.3161A>G p.D1054G | Missense Mutation (SNP) | VAF 104/192 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs891691796, COSV100823879; called by muse, mutect2, varscan2
- ANKRD30A | c.2743C>T p.Q915* (on ENST00000611781; = p.Q859* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 214/540 reads (40%) | catalogued as COSV100654517; called by muse, mutect2, varscan2
- ANKRD6 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100330364; called by muse, mutect2
- ARPP21 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1197581584, COSV51808867; called by muse, mutect2, varscan2
- ASB5 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as COSV99642165; called by muse, mutect2, varscan2
- ASTN2 | c.1468G>A p.D490N (on ENST00000313400 / NM_001365069.1; = p.D439N on NM_014010.5) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs756643087, COSV57779489; called by muse, mutect2, varscan2
- ATP11A | c.3292C>T p.R1098W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs765783405, COSV52118057; called by muse, varscan2
- ATP2B3 | c.2744G>A p.G915D | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV54855338; called by muse, mutect2, varscan2
- C6 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 226/676 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as rs373830541, COSV54714093; called by muse, mutect2, varscan2
- CALN1 | c.565G>A p.V189I (on ENST00000329008 / NM_001017440.3; = p.V231I on NM_031468.4) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs144352678; called by muse, mutect2, varscan2
- CATIP | c.465A>G p.E155= | Splice Region (SNP) | VAF 4/38 reads (11%) | catalogued as rs965828482, COSV99179654; called by muse, mutect2
- CDH10 | c.1028T>A p.L343H | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV100053296; called by muse, mutect2, varscan2
- CDH4 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777402708, COSV64643579; called by muse, mutect2, varscan2
- CFLAR | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV58580066, COSV58581331; called by muse, mutect2, varscan2
- CLVS1 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.166); catalogued as rs778256447, COSV57979471; called by muse, mutect2, varscan2
- CNTNAP5 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs145480371; called by muse, mutect2, varscan2
- CSF1 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100294848; called by muse, mutect2, varscan2
- CSMD3 | c.1438A>G p.K480E (on ENST00000297405 / NM_001363185.1; = p.K376E on NM_052900.3) | Missense Mutation (SNP) | VAF 197/683 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.437); catalogued as COSV99832461, COSV99849348; called by muse, mutect2, varscan2
- CYP27C1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776104127, COSV58867511; called by muse, mutect2, varscan2
- DRC7 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV61056786; called by muse, mutect2, varscan2
- EDEM1 | c.1700C>A p.P567Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56583394; called by muse, mutect2, varscan2
- EPX | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs151055641; called by muse, mutect2, varscan2
- FLG | c.11816C>T p.A3939V | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as rs200826810, COSV64252808; called by muse, mutect2, varscan2
- GPC6 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100990092; called by muse, varscan2
- GPR87 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778550664, COSV53464340; called by muse, mutect2, varscan2
- GRIK4 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs762037476, COSV70806237; called by muse, mutect2, varscan2
- GRM5 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776804851, COSV59590843; called by muse, mutect2, varscan2
- IDH2 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); catalogued as rs781481805, COSV99184288; called by muse, mutect2, varscan2
- KCNA3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63902582; called by muse, mutect2, varscan2
- KCNC2 | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100129992; called by muse, mutect2, varscan2
- KCNJ2 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs144022753, CM1110993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2C | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV64765228; called by muse, mutect2, varscan2
- LIG3 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.069); catalogued as COSV52009578; called by muse, mutect2, varscan2
- MAGEC1 | c.2096T>C p.L699P | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868021344, COSV99596666; called by muse, mutect2, varscan2
- MAP2 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV52300448; called by muse, mutect2, varscan2
- MPRIP | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs1462467430, COSV100506163; called by muse, mutect2, varscan2
- NAA15 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 129/409 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56719401; called by muse, mutect2, varscan2
- NBEA | c.5879T>A p.F1960Y | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100084718; called by muse, mutect2
- NOMO1 | c.2488G>A p.V830I | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV55060187; called by muse, mutect2, varscan2
- NPAP1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs138683847; called by muse, mutect2, varscan2
- NRXN1 | c.3647G>A p.R1216H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765200132, COSV60486467, COSV60508284; ClinVar: uncertain significance; called by muse, varscan2
- OR5I1 | c.133A>T p.I45F | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV56888259; called by muse, mutect2, varscan2
- PCDH11Y | c.304G>A p.G102R (on ENST00000400457 / NM_032973.2; = p.G91R on NM_032971.3) | Missense Mutation (SNP) | VAF 120/169 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV53086117; called by muse, mutect2, varscan2
- PHYHIPL | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as COSV100874241; called by muse, mutect2, varscan2
- PNPLA3 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372035117; called by muse, mutect2, varscan2
- PNPLA5 | c.866dup p.L290Pfs*19 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs1332647081; called by pindel, varscan2
- PRKD3 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 143/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99306840; called by muse, mutect2, varscan2
- PRPF4 | c.586C>T p.R196* (on ENST00000374198 / NM_001322267.2; = p.R197* on NM_004697.5) | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as COSV65253166; called by muse, mutect2, varscan2
- PTPRT | c.3344G>A p.C1115Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100630870, COSV61980487; called by muse, mutect2
- QRFPR | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as rs1176080303, COSV100543898; called by muse, mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as rs749563266; called by mutect2, varscan2
- RIMBP2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1407028798, COSV99900712; called by muse, mutect2, varscan2
- RYR1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.18); catalogued as COSV100617131, COSV62087075; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- SCN11A | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 121/332 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201421435, COSV56566143; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN2A | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs775923587, COSV51838768; called by muse, mutect2, varscan2
- SMC2 | c.2846G>T p.G949V | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53961536; called by muse, mutect2, varscan2
- SMUG1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs371582477; called by muse, mutect2, varscan2
- SPAG16 | c.1528-1G>A p.X510_splice | Splice Site (SNP) | VAF 410/982 reads (42%) | catalogued as rs1261256654, COSV100536132; called by muse, mutect2, varscan2
- TADA3 | c.288dup p.K97Qfs*38 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | catalogued as rs1300913222; called by pindel, varscan2
- TIAM1 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs777057988, COSV54541746; called by muse, mutect2, varscan2
- TMEM74 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372486464; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2107C>T p.H703Y | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV61457499; called by muse, mutect2, varscan2
- UBN1 | c.2749A>T p.S917C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV99278715; called by muse, mutect2, varscan2
- USH2A | c.7015A>C p.T2339P | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100243286; called by muse, mutect2
- VPS13A | c.1447A>C p.K483Q | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769826126, COSV100653614; called by muse, mutect2, varscan2
- WWOX | c.1016C>G p.T339R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68361445; called by muse, mutect2, varscan2
- ZNF226 | c.1957G>A p.G653S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.566); catalogued as rs771124673, COSV56197372; called by muse, mutect2, varscan2
- ZNF407 | c.5036C>T p.T1679M | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs976526612, COSV55241900; called by muse, mutect2, varscan2
- APC | c.4359_4360insTT p.K1454Lfs*20 | Frame Shift Ins (INS) | VAF 103/160 reads (64%) | called by mutect2, pindel, varscan2
- ARG2 | c.1053_1058dup p.V352_R353insSV | In Frame Ins (INS) | VAF 34/96 reads (35%) | called by mutect2, varscan2
- ARV1 | c.320_321dup p.L108Vfs*8 | Frame Shift Ins (INS) | VAF 213/691 reads (31%) | called by mutect2, pindel, varscan2
- NME8 | c.1644_1646del p.P549del | In Frame Del (DEL) | VAF 83/165 reads (50%) | called by mutect2, pindel, varscan2
- PLCXD1 | c.94dup p.W32Lfs*172 | Frame Shift Ins (INS) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- PRR12 | c.3083T>C p.M1028T (on ENST00000615927; = p.M1849T on NM_020719.3) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.765); called by muse, varscan2
- TCOF1 | c.3438_3446del p.E1147_S1149del (on ENST00000377797 / NM_001135243.1; = p.E1070_S1072del on NM_000356.4) | In Frame Del (DEL) | VAF 24/34 reads (71%) | called by mutect2, pindel, varscan2
- TP53 | c.990dup p.Q331Sfs*6 | Frame Shift Ins (INS) | VAF 125/240 reads (52%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.4536C>T p.R1512= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV56361954; called by muse, mutect2, varscan2
- CDC42BPB | c.519G>A p.P173= | Silent (SNP) | VAF 104/262 reads (40%) | catalogued as rs377547128; called by muse, mutect2, varscan2
- CHRNB3 | c.375C>T p.F125= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1053084474, COSV51494803, COSV99251439; called by muse, varscan2
- CNR1 | c.708G>A p.A236= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs577054667, COSV62988555; called by muse, mutect2
- CTNND1 | c.558C>T p.G186= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV62385007; called by muse, mutect2, varscan2
- GFI1B | c.231G>A p.P77= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs768614274, COSV59744622; called by muse, mutect2, varscan2
- GJC1 | c.312C>T p.H104= | Silent (SNP) | VAF 62/94 reads (66%) | catalogued as rs147188720; called by muse, varscan2
- ISLR | c.780C>T p.D260= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs751736968; called by muse, mutect2
- NCOR1 | c.4257G>A p.P1419= | Silent (SNP) | VAF 83/154 reads (54%) | catalogued as rs143182424; called by muse, mutect2, varscan2
- NPR2 | c.927C>T p.F309= | Silent (SNP) | VAF 154/397 reads (39%) | catalogued as rs1329117188, COSV61313163; called by muse, mutect2, varscan2
- PKHD1 | c.11328C>A p.S3776= | Silent (SNP) | VAF 102/284 reads (36%) | catalogued as COSV64395861, COSV64398081; called by muse, mutect2, varscan2
- PLCB2 | c.1992G>A p.P664= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs774830264, COSV53032558; called by muse, mutect2
- RIMBP2 | c.585G>A p.T195= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs781308063, COSV55479322; called by muse, mutect2, varscan2
- SCLY | c.567C>T p.L189= (on ENST00000651534; = p.L181= on NM_016510.7) | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs774413830, COSV54540610; called by muse, mutect2, varscan2
- TMEM178A | c.870G>A p.K290= | Silent (SNP) | VAF 75/201 reads (37%) | catalogued as rs1230151916, COSV56142762; called by muse, mutect2, varscan2
- TRIML1 | c.852C>T p.F284= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV60195744; called by muse, mutect2, varscan2
- XDH | c.684A>T p.R228= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV65150280; called by muse, varscan2
- ZNF671 | c.1032C>T p.S344= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV58053741; called by muse, mutect2, varscan2
- LILRB4 | c.-1C>T | 5'UTR (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99554153; called by muse, varscan2
- NRXN1 | c.3719-1436G>A | Intron (SNP) | VAF 64/167 reads (38%) | catalogued as rs754724604, COSV60486133; called by muse, mutect2, varscan2
